Somatic mutation profile of tumor specimen C3L-06625-01 (aliquot CPT0406420007) from CPTAC case C3L-06625, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.4 years (25,709 days).
Specimen C3L-06625-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75ffaeec-0ca5-47e3-b7fe-ca39bfb27f94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06625-31 (Blood Derived Normal), aliquot CPT0405340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec9c85ed-ba3a-4c34-b61a-20903e0fd974

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 16 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Intron 6, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 1230/3907 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.1543G>A p.V515M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774245075; called by muse, mutect2, varscan2
- ACSM1 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369221835; called by muse, mutect2, varscan2
- ATG2A | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1224685678; called by muse, mutect2, varscan2
- ATP2B3 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs1342263352, COSV54850001; called by muse, mutect2, varscan2
- C3orf56 | c.536A>C p.Y179S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.322); catalogued as rs1370765678; called by muse, mutect2, varscan2
- C5AR2 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 174/591 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs139018520; called by muse, mutect2, varscan2
- CCDC154 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs568525805; called by muse, mutect2, varscan2
- CLASP1 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs767923805, COSV55342733; called by muse, mutect2, varscan2
- COBLL1 | c.2825C>A p.S942Y (on ENST00000392717; = p.S904Y on NM_014900.5) | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52077361; called by muse, mutect2, varscan2
- EXOC3L4 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 84/331 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.356); catalogued as rs1206510170; called by muse, mutect2
- GAS7 | c.320G>A p.R107H (on ENST00000432992 / NM_201433.2; = p.R47H on NM_201432.2) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.515); catalogued as rs150719505; called by muse, mutect2, varscan2
- GRID2IP | c.3010C>T p.R1004C | Missense Mutation (SNP) | VAF 54/482 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.761); catalogued as rs749344791; called by muse, mutect2, varscan2
- HHAT | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749916241, COSV54809497, COSV99805232; called by muse, mutect2, varscan2
- LOXHD1 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220335121, COSV59665550; called by muse, mutect2, varscan2
- LTBP2 | c.4076C>T p.A1359V | Missense Mutation (SNP) | VAF 123/499 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs755194699, COSV56205930; called by muse, mutect2, varscan2
- PCDH15 | c.4592G>A p.R1531H (on ENST00000644397 / NM_001354429.2; = p.R1480H on NM_001142769.3) | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs770967278, COSV64682528; called by muse, mutect2, varscan2
- PCDHGA1 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 122/429 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.537); catalogued as rs577475018, COSV65299631; called by muse, mutect2, varscan2
- PTGDR | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs764113828; called by muse, mutect2, varscan2
- SIGLEC8 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs200891335, COSV100367463; called by muse, mutect2, varscan2
- SLC5A3 | c.1591C>T p.L531F | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.16); catalogued as rs1234778394; called by muse, mutect2, varscan2
- SSTR4 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.087); catalogued as rs749577596, COSV54799500; called by muse, mutect2, varscan2
- TRA2B | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs1300746356, COSV52026125; called by muse, mutect2, varscan2
- TTC7B | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1256901331; called by muse, mutect2, varscan2
- USH2A | c.3552G>T p.L1184F | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761175679; called by muse, mutect2, varscan2
- USPL1 | c.880A>G p.K294E | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV99686940; called by muse, mutect2
- ZMYND8 | c.2881C>T p.R961C (on ENST00000311275 / NM_001363741.2; = p.R935C on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749035523; called by muse, mutect2, varscan2
- AKAP11 | c.3355_3357del p.K1119del | In Frame Del (DEL) | VAF 30/164 reads (18%) | called by pindel, varscan2
- AL592490.1 | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.026); called by muse, mutect2
- BRCA2 | c.2889A>G p.I963M | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CDH1 | c.415T>G p.L139V | Missense Mutation (SNP) | VAF 103/412 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTRB1 | c.271del p.Q91Rfs*11 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, varscan2
- DENND2A | c.1960-2A>G p.X654_splice | Splice Site (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- DLG3 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 103/338 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ECPAS | c.4516G>C p.E1506Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- EIF5A2 | c.323T>A p.V108D | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EXOC4 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 25/334 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.432); called by muse, mutect2
- FAT4 | c.7327G>T p.G2443* | Nonsense Mutation (SNP) | VAF 53/201 reads (26%) | called by muse, mutect2, varscan2
- H3C7 | c.27dup p.K10* | Frame Shift Ins (INS) | VAF 32/197 reads (16%) | called by mutect2, pindel, varscan2
- HEATR4 | c.1884C>T p.T628= | Splice Region (SNP) | VAF 46/170 reads (27%) | called by muse, mutect2, varscan2
- HECTD1 | c.4855A>G p.S1619G | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- IMPDH2 | c.589del p.A197Qfs*16 | Frame Shift Del (DEL) | VAF 76/332 reads (23%) | called by mutect2, pindel, varscan2
- ITGB7 | c.2066_2067del p.K689Rfs*16 | Frame Shift Del (DEL) | VAF 104/462 reads (23%) | called by mutect2, pindel, varscan2
- MAP3K19 | c.1948T>C p.F650L | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC16 | c.18207C>A p.D6069E | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PABPC1L2A | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by mutect2, varscan2
- PABPC1L2B | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- PCDH11X | c.2489T>C p.I830T | Missense Mutation (SNP) | VAF 114/403 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PDE10A | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHKA2 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 65/290 reads (22%) | called by muse, mutect2, varscan2
- PML | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TUBGCP3 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USP34 | c.9700dup p.Y3234Lfs*18 | Frame Shift Ins (INS) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- AGPAT1 | c.789G>A p.R263= | Silent (SNP) | VAF 14/227 reads (6%) | called by muse, mutect2
- ANKRD30B | c.3105C>T p.P1035= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs71350559, COSV100271432; called by muse, mutect2, varscan2
- ASB10 | c.1392C>T p.G464= (on ENST00000420175 / NM_001142459.2; = p.G449= on NM_080871.4) | Silent (SNP) | VAF 47/285 reads (16%) | catalogued as rs1486298590; called by muse, mutect2, varscan2
- CDKN2C | c.294C>T p.I98= | Silent (SNP) | VAF 62/292 reads (21%) | catalogued as rs200391870, COSV99395847; called by muse, mutect2, varscan2
- CLEC2L | c.387C>T p.H129= | Silent (SNP) | VAF 124/711 reads (17%) | called by muse, mutect2, varscan2
- EDA | c.888G>T p.L296= | Silent (SNP) | VAF 92/356 reads (26%) | called by muse, mutect2, varscan2
- FAM47C | c.1626C>T p.S542= | Silent (SNP) | VAF 143/544 reads (26%) | catalogued as rs1165492688, COSV63727594; called by muse, mutect2, varscan2
- GFI1B | c.45C>T p.Y15= | Silent (SNP) | VAF 99/423 reads (23%) | catalogued as rs369193177; called by muse, mutect2, varscan2
- LRRIQ1 | c.2511T>C p.S837= | Silent (SNP) | VAF 64/201 reads (32%) | called by muse, mutect2, varscan2
- MZF1 | c.1011C>T p.S337= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as rs544769321; called by muse, mutect2, varscan2
- NLRP2 | c.1320C>T p.G440= | Silent (SNP) | VAF 74/331 reads (22%) | catalogued as rs761761609, COSV99672477; called by muse, mutect2, varscan2
- OTUD6A | c.855G>A p.P285= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs748580751; called by muse, mutect2, varscan2
- SCN5A | c.5356C>T p.L1786= (on ENST00000333535 / NM_198056.3; = p.L1785= on NM_000335.5) | Silent (SNP) | VAF 149/604 reads (25%) | called by muse, mutect2, varscan2
- SLC24A2 | c.1416G>A p.T472= | Silent (SNP) | VAF 94/446 reads (21%) | catalogued as rs765178525, COSV53863100; called by muse, mutect2, varscan2
- SMC1A | c.2409C>T p.I803= | Silent (SNP) | VAF 135/628 reads (21%) | called by muse, mutect2, varscan2
- UNC79 | c.5865C>T p.N1955= (on ENST00000393151 / NM_001346218.2; = p.N1778= on NM_020818.5) | Silent (SNP) | VAF 84/281 reads (30%) | catalogued as rs745532875, COSV56374402, COSV56394379; called by muse, mutect2, varscan2
- ACTN1 | c.2521-28G>A | Intron (SNP) | VAF 46/201 reads (23%) | called by muse, mutect2, varscan2
- KRT5 | c.928-21C>T | Intron (SNP) | VAF 122/468 reads (26%) | catalogued as rs200170666; called by muse, mutect2, varscan2
- MARCHF1 | c.163-58G>A | Intron (SNP) | VAF 34/102 reads (33%) | catalogued as rs867829538, COSV56807759; called by muse, mutect2, varscan2
- MYL5 | c.187+69C>T | Intron (SNP) | VAF 52/199 reads (26%) | catalogued as rs773321678; called by muse, mutect2, varscan2
- PNPLA6 | c.3427+11G>T | Intron (SNP) | VAF 47/524 reads (9%) | catalogued as rs370597983, COSV55380843; ClinVar: uncertain significance; called by muse, mutect2
- SEC63 | c.1500+38A>G | Intron (SNP) | VAF 79/306 reads (26%) | called by muse, mutect2, varscan2
